Somatic mutation profile of tumor specimen 0DKRD4 from CCDI case PBBYRB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,715 days).
Specimen 0DKRD4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daea7d4f-7750-42fc-9406-9774bf1cc334.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKRCF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/313ead53-a851-41be-8909-7c3ac0c003f0

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, 3'UTR 2, 5'UTR 2, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.2820A>C p.E940D | Missense Mutation (SNP) | VAF 122/1325 reads (9%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV70025519, COSV70028233; called by muse, mutect2
- GAREM1 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs1243791533; called by muse, mutect2, varscan2
- MTHFD1 | c.1689C>G p.I563M | Missense Mutation (SNP) | VAF 138/847 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770631707; called by muse, mutect2, varscan2
- UBE4B | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 76/859 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.201); catalogued as COSV53530464; called by muse, mutect2
- VAV1 | c.1398G>C p.K466N | Missense Mutation (SNP) | VAF 185/973 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58384174; called by muse, mutect2, varscan2
- CCDC114 | c.1574G>C p.R525T | Missense Mutation (SNP) | VAF 140/652 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CEP76 | c.259C>G p.P87A | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- CSMD3 | c.3790A>C p.N1264H (on ENST00000297405 / NM_001363185.1; = p.N1160H on NM_052900.3) | Missense Mutation (SNP) | VAF 91/915 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ERN2 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 143/383 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FAM193A | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 162/861 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FRYL | c.8806T>G p.F2936V | Missense Mutation (SNP) | VAF 19/555 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGF2R | c.7432G>C p.V2478L | Missense Mutation (SNP) | VAF 21/720 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- LAMA2 | c.1052A>T p.E351V | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- NUP98 | c.4735_4745dup p.E1584Rfs*53 (on ENST00000359171 / NM_001365126.1; = p.E1567Rfs*53 on NM_016320.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 124/289 reads (43%) | called by mutect2, varscan2
- PPP6C | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 133/178 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRC2B | c.4108G>A p.A1370T | Missense Mutation (SNP) | VAF 133/386 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PTPRQ | c.6776T>C p.V2259A (on ENST00000616559; = p.V2226A on NM_001145026.2) | Missense Mutation (SNP) | VAF 72/856 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RAB26 | c.198C>A p.V66= | Splice Region (SNP) | VAF 383/515 reads (74%) | called by muse, mutect2, varscan2
- SPRY3 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 63/1810 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.07); called by muse, mutect2
- WDR75 | c.2168T>G p.L723* | Nonsense Mutation (SNP) | VAF 178/958 reads (19%) | called by muse, mutect2, varscan2
- COP1 | c.1899A>C p.L633= | Silent (SNP) | VAF 153/669 reads (23%) | called by muse, mutect2, varscan2
- NPY1R | c.798C>A p.L266= | Silent (SNP) | VAF 157/849 reads (18%) | called by muse, mutect2, varscan2
- OR11H12 | c.852G>T p.G284= | Silent (SNP) | VAF 74/776 reads (10%) | catalogued as rs1336257304; called by muse, mutect2, varscan2
- OR8K1 | c.624C>T p.F208= | Silent (SNP) | VAF 70/843 reads (8%) | catalogued as COSV54404674; called by muse, mutect2
- SACS | c.5319G>A p.R1773= | Silent (SNP) | VAF 236/923 reads (26%) | catalogued as rs1455125330, COSV66535230; called by muse, mutect2, varscan2
- SETD4 | c.774G>C p.T258= | Silent (SNP) | VAF 123/651 reads (19%) | called by muse, mutect2, varscan2
- TCN1 | c.1276T>C p.L426= | Silent (SNP) | VAF 177/550 reads (32%) | catalogued as rs751224176; called by muse, mutect2, varscan2
- CARNS1 | c.-204G>C | 5'UTR (SNP) | VAF 414/738 reads (56%) | called by muse, mutect2, varscan2
- CLDN23 | c.*36G>A | 3'UTR (SNP) | VAF 36/369 reads (10%) | called by muse, mutect2
- EIF1AY | c.-96G>A | 5'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- HFE | c.617-51T>A | Intron (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- SMAP2 | c.*72C>A | 3'UTR (SNP) | VAF 69/146 reads (47%) | catalogued as rs1223169806; called by muse, mutect2, varscan2
